Somatic mutation profile of tumor specimen MP2PRT-PARKNI-TMP1-A (aliquot MP2PRT-PARKNI-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARKNI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,489 days).
Specimen MP2PRT-PARKNI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fed7918c-ad66-4339-9d0c-834dab43b350.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKNI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKNI-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c066bf9-c959-45e6-862c-faf53c41530a

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 107/370 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADH1B | c.433A>G p.S145G | Missense Mutation (SNP) | VAF 148/531 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs769793596; called by muse, mutect2, varscan2
- BDNF | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 112/382 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100151544; called by muse, mutect2, varscan2
- CYP51A1 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs372185409; called by muse, mutect2, varscan2
- FAT1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 135/493 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749127676, COSV71675017; called by muse, mutect2, varscan2
- FAT2 | c.12763C>T p.R4255W | Missense Mutation (SNP) | VAF 34/638 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs765038227; called by muse, mutect2
- IGF2R | c.6763G>A p.G2255R | Missense Mutation (SNP) | VAF 139/578 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266187599; called by muse, mutect2, varscan2
- MED12 | c.4487G>A p.R1496H | Missense Mutation (SNP) | VAF 262/557 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866231134, COSV61359719; called by muse, mutect2, varscan2
- MATR3 | c.1625G>A p.R542K | Missense Mutation (SNP) | VAF 95/290 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SKOR2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 160/706 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.167); called by muse, varscan2
- CFAP221 | c.1107C>T p.H369= | Silent (SNP) | VAF 79/252 reads (31%) | catalogued as rs752797632, COSV54654617; called by muse, mutect2, varscan2
- PAPPA | c.1305C>T p.H435= | Silent (SNP) | VAF 226/652 reads (35%) | catalogued as rs371022168; called by muse, mutect2, varscan2
